Somatic mutation profile of tumor specimen TARGET-15-SJMPAL046471-09A.1 (aliquot TARGET-15-SJMPAL046471-09A.1-01D) from TARGET case TARGET-15-SJMPAL046471, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.0 years (730 days).
Specimen TARGET-15-SJMPAL046471-09A.1: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aa11e657-a4ac-4665-bdee-9fb56536ab2e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL046471-14A.1 (Bone Marrow Normal), aliquot TARGET-15-SJMPAL046471-14A.1-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/af0067ff-265f-4c6d-b853-eb171dee8a46

The open-access MAF lists 16 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 3, Nonsense Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- JAK3 | c.1970G>A p.R657Q | Missense Mutation (SNP) | VAF 45/101 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs758959409, COSV71685371; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ARHGEF26 | c.433C>A p.R145S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.007); catalogued as COSV62845270; called by mutect2, varscan2
- HIPK4 | c.1162G>T p.D388Y | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as COSV52520945; called by muse, mutect2
- RAB19 | c.583G>A p.G195S | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs144362151; called by muse, mutect2, varscan2
- ANXA6 | c.165G>T p.R55S | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- DGKZ | c.3138C>A p.N1046K (on ENST00000454345 / NM_001105540.2; = p.N858K on NM_003646.4) | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.75); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DHX8 | c.2315C>A p.P772Q | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.817); called by muse, mutect2
- DTX4 | c.1540C>A p.P514T | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- EML6 | c.4959C>A p.C1653* | Nonsense Mutation (SNP) | VAF 5/74 reads (7%) | called by muse, mutect2
- FLNA | c.3487G>T p.V1163F | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- PHLPP2 | c.2396G>T p.C799F | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SFI1 | c.2333C>A p.A778E (on ENST00000400288 / NM_001007467.3; = p.A747E on NM_014775.4) | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DYNC2H1 | c.2386C>A p.R796= | Silent (SNP) | VAF 5/90 reads (6%) | catalogued as COSV100517030, COSV62099488; called by muse, mutect2
- SEC24D | c.2247G>T p.V749= | Silent (SNP) | VAF 5/68 reads (7%) | called by muse, mutect2
- TOM1 | c.891C>A p.R297= | Silent (SNP) | VAF 4/16 reads (25%) | called by mutect2, varscan2
- WDR48 | chr3:39052004 C>A | 5'Flank (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
